Gene-level copy-number profile of tumor specimen TCGA-CM-5341-01A from TCGA case TCGA-CM-5341, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 82.6 years (30,163 days).
Specimen TCGA-CM-5341-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.d32d4e3f-bb18-458e-9e91-546c2bc4d3c7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CM-5341-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/68bf4811-d0f9-4973-9d50-05c2a1985fa7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,102; copy number 2: 7,029; copy number 3: 17,061; copy number 4: 28,014; copy number 5: 1,617; copy number 6: 1,440; copy number 7: 1,751; copy number 8: 170; copy number 9: 102; copy number 10: 1,534.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CM-5341-01A-01D-1406-01): tumor purity 0.51, ploidy 3.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,636 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 10 (broad region; genes not listed).
- chr17:39,063,313–39,154,394, 1 gene, copy number 9 (within-gene range 4–9): PLXDC1.
- chr17:39,156,894–41,072,341, 101 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
